Somatic mutation profile of tumor specimen HCM-BROD-0758-C43-06A (aliquot HCM-BROD-0758-C43-06A-01D-A85C-36) from HCMI case HCM-BROD-0758-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 55.3 years (20,195 days).
Specimen HCM-BROD-0758-C43-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e2856a6-5d0e-4885-83f3-a5b91b26fc5b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0758-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0758-C43-10A-01D-A85C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/035bb1e9-65ef-438d-946a-7c7fe26d1078

The open-access MAF lists 393 somatic variants for this specimen: 245 protein-altering or splice-affecting, 130 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 223, Silent 130, Nonsense Mutation 16, Intron 9, 3'UTR 4, 5'UTR 3, Splice Region 2, Splice Site 2, Frame Shift Ins 1, Frame Shift Del 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGL | c.2039G>A p.W680* | Nonsense Mutation (SNP) | VAF 178/384 reads (46%) | catalogued as rs113994129, CM960016; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARID1B | c.4831C>T p.R1611* | Nonsense Mutation (SNP) | VAF 223/339 reads (66%) | catalogued as rs1554236040, COSV51670259; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1921A>G p.K641E (on ENST00000288602 / NM_001374244.1; = p.K601E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 811/819 reads (99%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as rs121913364, CM092083, COSV56058494; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- OXA1L | c.169C>T p.L57F | Missense Mutation (SNP) | VAF 396/606 reads (65%) | hotspot (GDC flag); SIFT tolerated, low confidence (0.11); PolyPhen benign (0.208); catalogued as rs773412250, COSV53536555; called by muse, mutect2, varscan2
- SCN1A | c.4811G>A p.W1604* (on ENST00000303395 / NM_001202435.3; = p.W1593* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 88/473 reads (19%) | catalogued as rs794726800, CM1511236, COSV57668685; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC27A5 | c.1661C>T p.T554I | Missense Mutation (SNP) | VAF 210/490 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202081924, COSV54017957; called by muse, varscan2
- ABHD16B | c.865G>A p.G289R | Missense Mutation (SNP) | VAF 400/644 reads (62%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as rs1449405394, COSV53862321; called by muse, varscan2
- ABI3BP | c.2129G>A p.R710Q | Missense Mutation (SNP) | VAF 161/534 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as rs770109610, COSV52528036; called by muse, mutect2, varscan2
- ACSM1 | c.1432C>T p.R478C | Missense Mutation (SNP) | VAF 188/414 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.225); catalogued as rs905851561, COSV54632777; called by muse, varscan2
- ADAMTS7 | c.4013C>T p.P1338L | Missense Mutation (SNP) | VAF 194/1296 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1331914241; called by muse, varscan2
- ADAT3 | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 408/906 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.122); catalogued as rs752745048; called by muse, mutect2, varscan2
- ADCY10 | c.2683C>T p.R895C | Missense Mutation (SNP) | VAF 173/354 reads (49%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.959); catalogued as rs779053477, COSV63240979; called by muse, mutect2, varscan2
- AFM | c.992G>A p.G331E | Missense Mutation (SNP) | VAF 175/452 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs867565889, COSV56921393; called by muse, mutect2, varscan2
- AKR1C4 | c.659G>A p.G220E | Missense Mutation (SNP) | VAF 216/236 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1554798075, COSV99578659; called by muse, varscan2
- AKR1D1 | c.906G>C p.L302F | Missense Mutation (SNP) | VAF 102/1095 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV54338845; called by muse, mutect2
- AMPD2 | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 364/832 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.543); catalogued as rs778310718; called by muse, varscan2
- ANKS1B | c.3649C>T p.R1217C (on ENST00000547776 / NM_152788.4; = p.R383C on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 292/717 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs761350003, COSV100227188; called by muse, mutect2, varscan2
- ARHGAP6 | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 1407/1839 reads (77%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as COSV100272745; called by muse, varscan2
- ASB5 | c.566C>T p.S189F | Missense Mutation (SNP) | VAF 235/471 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.479); catalogued as rs1167022895; called by muse, mutect2, varscan2
- BTNL3 | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 264/273 reads (97%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV61564523; called by muse, mutect2, varscan2
- CACNA1E | c.5227G>A p.E1743K | Missense Mutation (SNP) | VAF 242/556 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV62385594; called by muse, varscan2
- CATSPER1 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 204/584 reads (35%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs774801543; called by muse, varscan2
- CCR2 | c.671G>A p.G224E | Missense Mutation (SNP) | VAF 241/393 reads (61%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.589); catalogued as COSV52749045; called by muse, mutect2, varscan2
- CEP128 | c.1627C>T p.R543* | Nonsense Mutation (SNP) | VAF 190/335 reads (57%) | catalogued as rs780056351, COSV99825760; called by muse, varscan2
- CFAP91 | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 175/275 reads (64%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.844); catalogued as COSV56341066; called by muse, mutect2, varscan2
- CHP2 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 252/526 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs761363152; called by muse, varscan2
- CNTNAP2 | c.1448G>A p.R483Q | Missense Mutation (SNP) | VAF 180/731 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0.189); catalogued as rs777884519, CM1313256, COSV62148925; called by muse, varscan2
- COL17A1 | c.761G>A p.G254E | Missense Mutation (SNP) | VAF 220/231 reads (95%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100793412; called by muse, varscan2
- COL4A4 | c.1469G>A p.G490E | Missense Mutation (SNP) | VAF 294/426 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1339269673, COSV61633544; called by muse, mutect2, varscan2
- COL5A3 | c.2105C>T p.S702L | Missense Mutation (SNP) | VAF 295/627 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.103); catalogued as rs139738587; called by muse, mutect2, varscan2
- COL6A5 | c.6016G>A p.D2006N (on ENST00000312481; = p.D2002N on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 119/397 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs914947395, COSV99592741; called by muse, varscan2
- COMMD5 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 448/885 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs546989702; called by muse, varscan2
- CRB1 | c.2029G>A p.E677K | Missense Mutation (SNP) | VAF 217/485 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as rs867230786, COSV66334082; called by muse, mutect2, varscan2
- CRISP2 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 97/369 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as COSV59253803; called by muse, mutect2, varscan2
- DCLK2 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 164/385 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV56198611; called by muse, varscan2
- DNAH5 | c.7273C>T p.R2425C | Missense Mutation (SNP) | VAF 64/258 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.772); catalogued as rs376707969; called by muse, varscan2
- ECE1 | c.2147C>T p.S716F | Missense Mutation (SNP) | VAF 202/486 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV51665767; called by muse, varscan2
- EEF1AKMT3 | c.336C>G p.I112M | Missense Mutation (SNP) | VAF 663/3077 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.944); catalogued as COSV55744230; called by muse, mutect2, varscan2
- ELAPOR1 | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 148/300 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1271600009; called by muse, varscan2
- EREG | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 191/404 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.234); catalogued as rs866675158, COSV55260744; called by muse, mutect2, varscan2
- ERICH3 | c.308G>A p.R103K | Missense Mutation (SNP) | VAF 93/233 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.129); catalogued as rs1248020610; called by muse, mutect2, varscan2
- ESAM | c.644C>T p.S215L | Missense Mutation (SNP) | VAF 171/583 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54034925; called by muse, mutect2, varscan2
- FAT4 | c.13867G>A p.D4623N | Missense Mutation (SNP) | VAF 360/773 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58710120; called by muse, mutect2, varscan2
- FGG | c.646G>A p.G216R | Missense Mutation (SNP) | VAF 191/460 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60196319; called by muse, mutect2, varscan2
- FSIP2 | c.19924C>T p.R6642* | Nonsense Mutation (SNP) | VAF 136/194 reads (70%) | catalogued as rs1208600297, COSV104420935; called by muse, varscan2
- FTMT | c.44C>T p.S15L | Missense Mutation (SNP) | VAF 374/396 reads (94%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.139); catalogued as COSV58419945; called by muse, varscan2
- GABRG1 | c.1088G>A p.G363E | Missense Mutation (SNP) | VAF 125/291 reads (43%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.593); catalogued as rs1408329621, COSV54960467; called by muse, mutect2, varscan2
- GH2 | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 340/363 reads (94%) | SIFT tolerated (0.08); PolyPhen benign (0.078); catalogued as rs771557060; called by muse, varscan2
- GIPC2 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 193/396 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs771262251; called by muse, mutect2, varscan2
- GOLGA6L4 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 1512/1701 reads (89%) | SIFT tolerated (0.15); PolyPhen benign (0.047); catalogued as rs1432337504; called by muse, varscan2
- GRIN2B | c.4036G>A p.E1346K | Missense Mutation (SNP) | VAF 348/728 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.12); catalogued as rs766060662, COSV101663026; called by muse, varscan2
- IGSF22 | c.2521G>A p.E841K (on ENST00000319338; = p.E942K on NM_173588.4) | Missense Mutation (SNP) | VAF 318/669 reads (48%) | SIFT tolerated (1); PolyPhen probably damaging (0.963); catalogued as COSV55010454; called by muse, mutect2, varscan2
- IRAK3 | c.1757C>T p.S586F | Missense Mutation (SNP) | VAF 180/391 reads (46%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); catalogued as COSV99706443; called by muse, mutect2, varscan2
- JUP | c.1016C>T p.S339F | Missense Mutation (SNP) | VAF 274/292 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60278932; called by muse, mutect2, varscan2
- KCNK5 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 354/795 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.882); catalogued as rs748673096, COSV63988552; called by muse, varscan2
- KCNT1 | c.1010G>T p.R337L (on ENST00000488444; = p.R356L on NM_020822.3) | Missense Mutation (SNP) | VAF 162/345 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV53700894; called by muse, varscan2
- KCNT2 | c.386G>A p.G129E | Missense Mutation (SNP) | VAF 91/214 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV54106340; called by muse, mutect2, varscan2
- KLK2 | c.688G>A p.G230S | Missense Mutation (SNP) | VAF 270/596 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1434880603; called by muse, mutect2, varscan2
- KRT4 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 106/397 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as rs758810156, COSV53407310; called by muse, varscan2
- LAMA2 | c.2087C>T p.A696V | Missense Mutation (SNP) | VAF 80/258 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV70355091; called by muse, varscan2
- LETM1 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 104/509 reads (20%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as rs1040223952, COSV57103100; called by muse, mutect2, varscan2
- LIN28A | c.341G>A p.G114E | Missense Mutation (SNP) | VAF 247/533 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as rs1557427180; called by muse, mutect2, varscan2
- LIPM | c.1192C>T p.R398C | Missense Mutation (SNP) | VAF 344/366 reads (94%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs532626102; called by muse, varscan2
- MAGEC1 | c.2909C>T p.P970L | Missense Mutation (SNP) | VAF 238/397 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs143297640, COSV53573257, COSV53573679; called by muse, varscan2
- MAMDC2 | c.1217G>A p.G406E | Missense Mutation (SNP) | VAF 347/364 reads (95%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101015129, COSV65858391; called by muse, varscan2
- MAP3K13 | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 92/298 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53983436; called by muse, varscan2
- MCTP2 | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 176/745 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as COSV59147313; called by muse, mutect2, varscan2
- MEPE | c.818G>A p.G273D | Missense Mutation (SNP) | VAF 128/302 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.061); catalogued as COSV63073518; called by muse, varscan2
- MIA2 | c.1825C>T p.P609S | Missense Mutation (SNP) | VAF 64/198 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.121); catalogued as rs144877390; called by muse, varscan2
- MORC1 | c.1969C>T p.P657S | Missense Mutation (SNP) | VAF 169/280 reads (60%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV51717195; called by muse, mutect2, varscan2
- MUC12 | c.15307G>A p.E5103K (on ENST00000379442; = p.E4960K on NM_001164462.1) | Missense Mutation (SNP) | VAF 344/1149 reads (30%) | SIFT tolerated (0.26); catalogued as COSV65199299; called by muse, mutect2, varscan2
- MUC16 | c.33007C>T p.L11003F | Missense Mutation (SNP) | VAF 351/740 reads (47%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.006); catalogued as COSV67464632; called by muse, mutect2, varscan2
- MUC16 | c.5816C>T p.S1939L | Missense Mutation (SNP) | VAF 155/384 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.765); catalogued as COSV67457357; called by muse, mutect2, varscan2
- NAA11 | c.544G>A p.G182S | Missense Mutation (SNP) | VAF 356/742 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs745372449, COSV54514317, COSV99727364; called by muse, varscan2
- NECTIN3 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 150/618 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1205844764; called by muse, mutect2
- NEFL | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 123/449 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as rs57848467, CM032289; ClinVar: not provided / uncertain significance; called by muse, mutect2, varscan2
- NIPAL1 | c.508G>A p.G170R | Missense Mutation (SNP) | VAF 187/458 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV55005885; called by muse, mutect2, varscan2
- NPTX2 | c.1069-1G>A p.X357_splice | Splice Site (SNP) | VAF 214/690 reads (31%) | catalogued as COSV99674599; called by muse, varscan2
- OGFOD2 | c.14G>A p.G5E | Missense Mutation (SNP) | VAF 229/648 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs1566208456; called by muse, varscan2
- OR10A2 | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 302/660 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.58); catalogued as COSV56298732; called by muse, varscan2
- OR2T2 | c.932C>T p.S311F | Missense Mutation (SNP) | VAF 211/518 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV61618765; called by muse, mutect2, varscan2
- PCDHB10 | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 320/342 reads (94%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.036); catalogued as rs189437073, COSV53379211; called by muse, varscan2
- PCOLCE2 | c.378G>A p.M126I | Missense Mutation (SNP) | VAF 150/516 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV55998856; called by muse, mutect2, varscan2
- PDE3A | c.2509G>A p.D837N | Missense Mutation (SNP) | VAF 118/374 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62973135; called by muse, varscan2
- PDE8B | c.644C>T p.S215L | Missense Mutation (SNP) | VAF 228/247 reads (92%) | SIFT tolerated (0.07); PolyPhen benign (0.22); catalogued as rs750904456, COSV53740558; called by muse, varscan2
- PHF21B | c.1408G>A p.A470T | Missense Mutation (SNP) | VAF 147/535 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs945696109; called by muse, mutect2, varscan2
- PHF3 | c.5326C>T p.P1776S | Missense Mutation (SNP) | VAF 136/476 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs1445822408, COSV50313855; called by muse, varscan2
- PIWIL2 | c.1273C>T p.R425C | Missense Mutation (SNP) | VAF 114/402 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs368245312; called by muse, varscan2
- PKHD1L1 | c.8635C>G p.R2879G | Missense Mutation (SNP) | VAF 64/650 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.509); catalogued as COSV101006194; called by muse, mutect2
- PLCL2 | c.1381C>T p.R461* (on ENST00000615277 / NM_001144382.2; = p.R335* on NM_015184.5) | Nonsense Mutation (SNP) | VAF 106/342 reads (31%) | catalogued as COSV67621776; called by muse, varscan2
- PLXNA3 | c.1724C>T p.A575V | Missense Mutation (SNP) | VAF 251/942 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1357426105; called by muse, varscan2
- PNPLA6 | c.4082G>A p.R1361Q (on ENST00000414982 / NM_001166111.2; = p.R1313Q on NM_006702.5) | Missense Mutation (SNP) | VAF 367/767 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs779790168; called by muse, mutect2, varscan2
- PPP1R3A | c.1936C>T p.Q646* | Nonsense Mutation (SNP) | VAF 179/682 reads (26%) | catalogued as COSV52882407; called by muse, mutect2, varscan2
- PRAMEF4 | c.425G>A p.R142K | Missense Mutation (SNP) | VAF 620/652 reads (95%) | SIFT tolerated (0.22); PolyPhen benign (0.117); catalogued as rs778299374; called by muse, varscan2
- PROK2 | c.350G>A p.R117Q (on ENST00000295619 / NM_001126128.2; = p.R96Q on NM_021935.4) | Missense Mutation (SNP) | VAF 165/434 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as rs1396253995, COSV55208496; called by muse, varscan2
- PRRC2C | c.8066C>T p.P2689L (on ENST00000367742; = p.P2687L on NM_015172.4) | Missense Mutation (SNP) | VAF 189/418 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV58913028; called by muse, mutect2, varscan2
- PRUNE1 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 162/382 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); catalogued as COSV54958885; called by muse, mutect2, varscan2
- PTPRB | c.3842G>A p.W1281* | Nonsense Mutation (SNP) | VAF 98/386 reads (25%) | catalogued as COSV54232440; called by muse, varscan2
- PTPRQ | c.508G>A p.E170K (on ENST00000616559; = p.E128K on NM_001145026.2) | Missense Mutation (SNP) | VAF 132/137 reads (96%) | SIFT tolerated (0.3); PolyPhen benign (0.108); catalogued as rs1479476966; called by muse, varscan2
- RABEP2 | c.1055T>G p.V352G | Missense Mutation (SNP) | VAF 324/657 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.351); catalogued as COSV62869951; called by muse, mutect2, varscan2
- RASL12 | c.239C>T p.T80I | Missense Mutation (SNP) | VAF 206/941 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs769143677; called by muse, mutect2, varscan2
- RBMXL2 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 406/955 reads (43%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs1228883467; called by muse, varscan2
- RGPD4 | c.4121G>A p.W1374* | Nonsense Mutation (SNP) | VAF 102/522 reads (20%) | catalogued as COSV61749561; called by muse, varscan2
- RNASET2 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 80/279 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as rs774543357; called by muse, varscan2
- RTN3 | c.188C>T p.S63L | Missense Mutation (SNP) | VAF 196/328 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.719); catalogued as rs772966959; called by muse, mutect2, varscan2
- RUNX1T1 | c.797G>A p.R266Q (on ENST00000265814 / NM_001198628.1; = p.R239Q on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 279/693 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1359364143, COSV99750353; called by muse, mutect2, varscan2
- SBNO1 | c.1124C>T p.S375L (on ENST00000420886; = p.S374L on NM_018183.5) | Missense Mutation (SNP) | VAF 46/182 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.65); catalogued as rs147276203, COSV57345269; called by mutect2, varscan2
- SGCE | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 201/677 reads (30%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.044); catalogued as rs761677071, COSV56016470; called by muse, mutect2, varscan2
- SIRPG | c.17C>T p.S6F | Missense Mutation (SNP) | VAF 236/255 reads (93%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as rs1281567353, COSV53805960; called by muse, varscan2
- SLC2A2 | c.736C>T p.L246F | Missense Mutation (SNP) | VAF 162/262 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100049134, COSV58586598; called by muse, varscan2
- SLC6A14 | c.170G>A p.G57E | Missense Mutation (SNP) | VAF 123/459 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64147231; called by muse, varscan2
- SPEF2 | c.4961G>A p.G1654E | Missense Mutation (SNP) | VAF 124/412 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV57428581; called by muse, varscan2
- SPOCD1 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 285/587 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs561311491, COSV57096942; called by muse, varscan2
- ST18 | c.1345G>A p.D449N | Missense Mutation (SNP) | VAF 380/645 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as rs1180624281, COSV52488986; called by muse, mutect2, varscan2
- SULT1C4 | c.704C>T p.S235L | Missense Mutation (SNP) | VAF 356/512 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs750911106, COSV55597757; called by muse, mutect2, varscan2
- SYN3 | c.862G>A p.D288N | Missense Mutation (SNP) | VAF 353/570 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs781427098, COSV60506596; called by muse, mutect2, varscan2
- SYT5 | c.871C>T p.R291W | Missense Mutation (SNP) | VAF 286/660 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV62830068; called by muse, varscan2
- TAOK3 | c.2116C>T p.R706W | Missense Mutation (SNP) | VAF 901/1142 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1277510978, COSV101183685; called by muse, varscan2
- TBC1D14 | c.2071C>T p.L691F | Missense Mutation (SNP) | VAF 180/393 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.045); catalogued as rs1350297845; called by muse, mutect2, varscan2
- TCAIM | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 41/192 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs765468418, COSV61240135; called by muse, mutect2, varscan2
- TENM2 | c.3845G>A p.S1282N | Missense Mutation (SNP) | VAF 15/18 reads (83%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.697); catalogued as rs1163257568; called by muse, mutect2, varscan2
- TENT4B | c.1277G>A p.R426Q (on ENST00000561678 / NM_001365323.2; = p.R411Q on NM_001040284.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 250/255 reads (98%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV62549294; called by muse, varscan2
- TGM1 | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 390/604 reads (65%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.025); catalogued as rs1445996067; called by muse, varscan2
- TOP3A | c.2294G>A p.R765H | Missense Mutation (SNP) | VAF 180/586 reads (31%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs757039121, COSV58178210, COSV58178822; called by muse, varscan2
- TP53 | c.632C>T p.T211I | Missense Mutation (SNP) | VAF 427/438 reads (97%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV52665474, COSV52751752, COSV52987532; called by muse, mutect2, varscan2
- TRAV7 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 111/355 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs946727967; called by muse, varscan2
- TRIML1 | c.1337C>T p.S446F | Missense Mutation (SNP) | VAF 284/582 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as rs1316000776, COSV60194018, COSV60196036; called by muse, mutect2, varscan2
- TTC6 | c.2534A>T p.D845V | Missense Mutation (SNP) | VAF 121/358 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); catalogued as rs758262904; called by muse, mutect2, varscan2
- TTN | c.4112G>A p.G1371E (on ENST00000591111; = p.G1325E on NM_003319.4) | Missense Mutation (SNP) | VAF 368/482 reads (76%) | PolyPhen probably damaging (1); catalogued as rs267599090, COSV60214092; called by muse, mutect2, varscan2
- UBQLN3 | c.1454C>T p.S485F | Missense Mutation (SNP) | VAF 316/656 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.352); catalogued as rs773974129; called by muse, mutect2, varscan2
- UCKL1 | c.303C>T p.I101= | Splice Region (SNP) | VAF 206/333 reads (62%) | catalogued as rs201407701; called by muse, mutect2, varscan2
- WDR87 | c.7984G>A p.E2662K | Missense Mutation (SNP) | VAF 284/583 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.083); catalogued as COSV58192643; called by muse, varscan2
- ZNF479 | c.246G>A p.M82I | Missense Mutation (SNP) | VAF 145/612 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.066); catalogued as rs535878108, COSV58635779; called by muse, mutect2, varscan2
- ZNF490 | c.814C>T p.H272Y | Missense Mutation (SNP) | VAF 214/495 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs539425301, COSV61008916; called by muse, mutect2, varscan2
- ZNF517 | c.1349G>A p.R450K | Missense Mutation (SNP) | VAF 556/1194 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs754474284; called by muse, varscan2
- ZNF777 | c.2258C>T p.P753L | Missense Mutation (SNP) | VAF 454/1902 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV99925400; called by muse, varscan2
- ZNF831 | c.785G>A p.R262K | Missense Mutation (SNP) | VAF 189/625 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1003756292; called by muse, varscan2
- ZNF831 | c.2972G>A p.S991N | Missense Mutation (SNP) | VAF 192/643 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.176); catalogued as rs1228989095; called by muse, varscan2
- ACSM3 | c.255G>A p.W85* | Nonsense Mutation (SNP) | VAF 185/443 reads (42%) | called by muse, mutect2, varscan2
- ADAM15 | c.593G>A p.G198E | Missense Mutation (SNP) | VAF 265/546 reads (49%) | SIFT tolerated (0.37); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ANK3 | c.4426G>A p.G1476R (on ENST00000280772 / NM_001320874.2; = p.G601R on NM_001149.3) | Missense Mutation (SNP) | VAF 186/199 reads (93%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ARHGEF1 | c.2225C>T p.A742V | Missense Mutation (SNP) | VAF 94/512 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- ARMCX5 | c.1465G>A p.A489T | Missense Mutation (SNP) | VAF 68/269 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.029); called by muse, varscan2
- BAP1 | c.1751C>T p.P584L | Missense Mutation (SNP) | VAF 296/463 reads (64%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, varscan2
- BAZ2A | c.4177G>A p.E1393K | Missense Mutation (SNP) | VAF 162/1074 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- BEND7 | c.963A>C p.R321S | Missense Mutation (SNP) | VAF 226/236 reads (96%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CADPS | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 365/548 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- CARMIL2 | c.775G>A p.G259R | Missense Mutation (SNP) | VAF 176/188 reads (94%) | SIFT tolerated (0.14); PolyPhen benign (0.214); called by muse, varscan2
- CARMIL2 | c.2083-1G>A p.X695_splice | Splice Site (SNP) | VAF 245/260 reads (94%) | called by muse, varscan2
- CCDC141 | c.2269C>T p.P757S | Missense Mutation (SNP) | VAF 338/506 reads (67%) | SIFT tolerated (0.09); PolyPhen benign (0.17); called by muse, varscan2
- CCDC168 | c.11614G>A p.E3872K | Missense Mutation (SNP) | VAF 124/236 reads (53%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- CEMIP | c.1487G>A p.R496Q | Missense Mutation (SNP) | VAF 161/1380 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, varscan2
- CNOT2 | c.400A>T p.M134L | Missense Mutation (SNP) | VAF 150/224 reads (67%) | SIFT tolerated, low confidence (0.33); PolyPhen possibly damaging (0.746); called by muse, varscan2
- CNOT2 | c.401T>A p.M134K | Missense Mutation (SNP) | VAF 152/228 reads (67%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.916); called by muse, varscan2
- COL10A1 | c.1520C>T p.P507L | Missense Mutation (SNP) | VAF 288/479 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.243); called by muse, varscan2
- CORO2A | c.872G>A p.G291E | Missense Mutation (SNP) | VAF 190/204 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CR1 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 369/825 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- DCHS1 | c.8387_8388del p.S2796Cfs*12 | Frame Shift Del (DEL) | VAF 136/689 reads (20%) | called by pindel, varscan2
- DIO2 | c.326G>A p.G109E | Missense Mutation (SNP) | VAF 276/440 reads (63%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, varscan2
- DMD | c.2254A>G p.K752E | Missense Mutation (SNP) | VAF 116/275 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.937); called by muse, varscan2
- DNAH2 | c.7250C>T p.P2417L | Missense Mutation (SNP) | VAF 504/525 reads (96%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- DNAH8 | c.9844G>A p.G3282S | Missense Mutation (SNP) | VAF 193/430 reads (45%) | SIFT tolerated (0.92); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- DTWD2 | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 566/600 reads (94%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); called by muse, varscan2
- DTX1 | c.1450C>T p.P484S | Missense Mutation (SNP) | VAF 611/1051 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.254); called by muse, varscan2
- ELAVL2 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 131/151 reads (87%) | SIFT deleterious (0.01); PolyPhen benign (0.043); called by muse, varscan2
- FAM71E2 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 380/840 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, varscan2
- GOLGA3 | c.680G>A p.G227E | Missense Mutation (SNP) | VAF 296/818 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.898); called by muse, varscan2
- HEATR3 | c.577T>C p.Y193H | Missense Mutation (SNP) | VAF 70/164 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- HHIPL2 | c.974G>A p.R325K | Missense Mutation (SNP) | VAF 130/282 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.874); called by muse, varscan2
- HOXA13 | c.32G>A p.W11* | Nonsense Mutation (SNP) | VAF 407/1241 reads (33%) | called by muse, mutect2, varscan2
- HSP90AB1 | c.1663G>A p.E555K | Missense Mutation (SNP) | VAF 255/623 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- HTR1B | c.1103T>G p.I368S | Missense Mutation (SNP) | VAF 234/368 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- IFT122 | c.1066C>T p.H356Y (on ENST00000348417 / NM_052989.3; = p.H297Y on NM_018262.4) | Missense Mutation (SNP) | VAF 302/507 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- IP6K3 | c.1226G>A p.G409E | Missense Mutation (SNP) | VAF 106/216 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- IQCF1 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 113/177 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, varscan2
- ITGA9 | c.677T>G p.L226R | Missense Mutation (SNP) | VAF 224/368 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- ITK | c.1068G>A p.W356* | Nonsense Mutation (SNP) | VAF 181/205 reads (88%) | called by muse, varscan2
- KANSL3 | c.1588C>T p.L530F | Missense Mutation (SNP) | VAF 283/396 reads (71%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.012); called by muse, varscan2
- KCNJ15 | c.947C>T p.S316F | Missense Mutation (SNP) | VAF 118/386 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0.094); called by muse, varscan2
- KIRREL3 | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 243/390 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- L1TD1 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 147/346 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LMAN2L | c.760T>C p.S254P | Missense Mutation (SNP) | VAF 116/506 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LRRC8B | c.1323A>C p.E441D | Missense Mutation (SNP) | VAF 273/570 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, varscan2
- MAGED1 | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 132/422 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.679); called by muse, varscan2
- MARK3 | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 191/331 reads (58%) | SIFT tolerated (0.31); PolyPhen benign (0.402); called by muse, mutect2, varscan2
- MMP28 | c.1252C>T p.P418S | Missense Mutation (SNP) | VAF 530/556 reads (95%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- MMRN1 | c.2853T>A p.H951Q | Missense Mutation (SNP) | VAF 274/540 reads (51%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, varscan2
- MROH7 | c.501C>G p.N167K | Missense Mutation (SNP) | VAF 328/693 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NAV3 | c.1691C>T p.S564F | Missense Mutation (SNP) | VAF 151/486 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NDST4 | c.130A>G p.I44V | Missense Mutation (SNP) | VAF 105/374 reads (28%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NOL4 | c.1168G>A p.D390N | Missense Mutation (SNP) | VAF 140/460 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- OGFOD2 | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 226/640 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.006); called by muse, varscan2
- OR10H1 | c.143C>T p.T48I | Missense Mutation (SNP) | VAF 317/662 reads (48%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.963); called by muse, varscan2
- OR10S1 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 284/468 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.241); called by muse, varscan2
- OR51Q1 | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 202/452 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- OXNAD1 | c.-8-8T>G | Splice Region (SNP) | VAF 323/536 reads (60%) | called by muse, varscan2
- PAPLN | c.614C>T p.P205L | Missense Mutation (SNP) | VAF 159/506 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); called by muse, varscan2
- PAPPA2 | c.5191C>T p.Q1731* | Nonsense Mutation (SNP) | VAF 273/588 reads (46%) | called by muse, mutect2, varscan2
- PGK2 | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 248/416 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- PGPEP1L | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 316/1201 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.062); called by muse, varscan2
- PIP5K1A | c.1102C>T p.Q368* (on ENST00000368888 / NM_001135638.2; = p.Q355* on NM_003557.3) | Nonsense Mutation (SNP) | VAF 250/518 reads (48%) | called by muse, mutect2, varscan2
- POM121L2 | c.2990C>T p.S997F | Missense Mutation (SNP) | VAF 296/626 reads (47%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.519); called by muse, varscan2
- PPID | c.991A>G p.K331E | Missense Mutation (SNP) | VAF 190/451 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PRKAG2 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 296/1282 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.674); called by muse, varscan2
- PRKG2 | c.2171T>A p.L724H | Missense Mutation (SNP) | VAF 164/378 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- PRMT8 | c.766A>C p.K256Q | Missense Mutation (SNP) | VAF 140/427 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, varscan2
- PROS1 | c.2010G>A p.W670* | Nonsense Mutation (SNP) | VAF 72/256 reads (28%) | called by muse, mutect2
- PSG9 | c.394A>G p.R132G | Missense Mutation (SNP) | VAF 128/252 reads (51%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTPN22 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 243/527 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPRK | c.595C>T p.L199F | Missense Mutation (SNP) | VAF 104/350 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); called by muse, varscan2
- PTPRQ | c.4228G>A p.G1410R (on ENST00000616559; = p.G1368R on NM_001145026.2) | Missense Mutation (SNP) | VAF 204/231 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RASA3 | c.65A>G p.K22R | Missense Mutation (SNP) | VAF 83/314 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RASSF10 | c.513G>T p.E171D | Missense Mutation (SNP) | VAF 226/963 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- RBMXL2 | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 405/948 reads (43%) | SIFT tolerated (0.6); PolyPhen benign (0.013); called by muse, varscan2
- REELD1 | c.1280G>A p.G427E | Missense Mutation (SNP) | VAF 260/634 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.06); called by muse, varscan2
- RINL | c.1168C>T p.P390S (on ENST00000591812 / NM_001195833.2; = p.P276S on NM_198445.4) | Missense Mutation (SNP) | VAF 476/1018 reads (47%) | SIFT tolerated (0.53); PolyPhen benign (0.005); called by muse, varscan2
- RTP2 | c.533C>T p.T178I | Missense Mutation (SNP) | VAF 148/556 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.006); called by muse, varscan2
- SCFD1 | c.515C>T p.S172L | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SCN11A | c.1079C>T p.S360F | Missense Mutation (SNP) | VAF 94/360 reads (26%) | SIFT tolerated (0.66); PolyPhen benign (0.113); called by muse, varscan2
- SDSL | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 556/1027 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEMA5A | c.1790G>C p.G597A | Missense Mutation (SNP) | VAF 238/388 reads (61%) | SIFT tolerated (0.38); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- SHMT1 | c.1350G>C p.E450D | Missense Mutation (SNP) | VAF 175/641 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC30A8 | c.601C>T p.L201F | Missense Mutation (SNP) | VAF 290/646 reads (45%) | SIFT tolerated (0.71); PolyPhen benign (0.009); called by muse, varscan2
- SLFN11 | c.397T>A p.Y133N | Missense Mutation (SNP) | VAF 322/340 reads (95%) | SIFT deleterious (0.01); PolyPhen benign (0.319); called by muse, mutect2
- SPANXB1 | c.245G>A p.R82K | Missense Mutation (SNP) | VAF 110/948 reads (12%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.87); called by muse, varscan2
- SSU72P8 | c.253T>A p.L85M | Missense Mutation (SNP) | VAF 262/736 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- STAP2 | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 226/482 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- TARBP2 | c.628A>T p.K210* (on ENST00000266987 / NM_134323.2; = p.K189* on NM_004178.4) | Nonsense Mutation (SNP) | VAF 82/281 reads (29%) | called by muse, mutect2, varscan2
- TDG | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 104/381 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TFCP2L1 | c.292-1_292insC p.S98Qfs*9 | Frame Shift Ins (INS) | VAF 276/592 reads (47%) | called by pindel, varscan2
- TGM6 | c.1667G>A p.G556E | Missense Mutation (SNP) | VAF 226/237 reads (95%) | SIFT tolerated (0.13); PolyPhen benign (0.025); called by muse, varscan2
- TMCC3 | c.575C>T p.S192L | Missense Mutation (SNP) | VAF 305/745 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- TMEM132C | c.1912G>T p.G638W | Missense Mutation (SNP) | VAF 262/510 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- TMEM132C | c.2686C>T p.P896S | Missense Mutation (SNP) | VAF 535/963 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- TOPAZ1 | c.2498C>T p.S833F | Missense Mutation (SNP) | VAF 81/307 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.018); called by muse, varscan2
- TRAV9-1 | c.154C>T p.L52F | Missense Mutation (SNP) | VAF 123/492 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRBV24-1 | c.244G>A p.G82R | Missense Mutation (SNP) | VAF 203/1134 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- TTN | c.23845T>A p.F7949I (on ENST00000591111; = p.F7022I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 284/410 reads (69%) | PolyPhen benign (0.172); called by muse, varscan2
- VWC2 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 513/1602 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.197); called by muse, varscan2
- WDR97 | c.4814C>T p.P1605L | Missense Mutation (SNP) | VAF 209/1299 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.45); called by muse, varscan2
- ZBTB16 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 130/399 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- ZNF169 | c.1285C>T p.P429S | Missense Mutation (SNP) | VAF 332/362 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ZNF260 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 198/458 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, varscan2
- ZNF711 | c.2008C>T p.H670Y | Missense Mutation (SNP) | VAF 263/407 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZNF774 | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 170/706 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- ABCC1 | c.2373C>T p.F791= | Silent (SNP) | VAF 482/1105 reads (44%) | catalogued as rs748257791, COSV100579890; called by muse, mutect2, varscan2
- ADAMTSL4 | c.417G>A p.E139= | Silent (SNP) | VAF 221/468 reads (47%) | catalogued as rs1299076621; called by muse, mutect2, varscan2
- AFDN | c.4620C>T p.I1540= | Silent (SNP) | VAF 172/524 reads (33%) | called by muse, varscan2
- AHSA1 | c.207C>T p.S69= | Silent (SNP) | VAF 136/446 reads (30%) | called by muse, varscan2
- ANKRD33 | c.39C>T p.A13= (on ENST00000340970 / NM_001304459.2; = p.A148= on NM_182608.4) | Silent (SNP) | VAF 1388/1721 reads (81%) | called by muse, varscan2
- ANKRD61 | c.90G>A p.S30= | Silent (SNP) | VAF 289/989 reads (29%) | catalogued as rs1324997677, COSV52240803; called by muse, mutect2, varscan2
- ANKS1B | c.1116A>T p.G372= | Silent (SNP) | VAF 80/427 reads (19%) | called by muse, mutect2, varscan2
- ANO2 | c.2676G>A p.S892= (on ENST00000356134 / NM_001278597.3; = p.S896= on NM_001278596.3) | Silent (SNP) | VAF 226/408 reads (55%) | catalogued as rs1179397959, COSV59019081; called by muse, varscan2
- ATG2B | c.3753C>T p.P1251= | Silent (SNP) | VAF 125/233 reads (54%) | called by muse, mutect2, varscan2
- ATG9B | c.72G>A p.S24= | Silent (SNP) | VAF 1130/1156 reads (98%) | catalogued as rs1239776376; called by muse, varscan2
- C19orf57 | c.1221C>T p.P407= | Silent (SNP) | VAF 378/809 reads (47%) | called by muse, varscan2
- C2CD2 | c.1032G>A p.T344= | Silent (SNP) | VAF 224/362 reads (62%) | catalogued as rs371481450; called by muse, mutect2, varscan2
- CACNA1E | c.1033C>T p.L345= | Silent (SNP) | VAF 226/437 reads (52%) | catalogued as rs745797769; called by muse, mutect2, varscan2
- CELSR1 | c.3174C>T p.A1058= | Silent (SNP) | VAF 209/577 reads (36%) | catalogued as COSV53097860; called by muse, varscan2
- CELSR3 | c.6810C>T p.A2270= | Silent (SNP) | VAF 394/659 reads (60%) | catalogued as rs1177194655; called by muse, mutect2, varscan2
- CFAP58 | c.1266G>A p.Q422= | Silent (SNP) | VAF 246/262 reads (94%) | called by muse, varscan2
- CNDP2 | c.1026C>T p.I342= | Silent (SNP) | VAF 152/473 reads (32%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.3663G>A p.G1221= | Silent (SNP) | VAF 95/432 reads (22%) | catalogued as COSV70472957; called by muse, mutect2, varscan2
- COL5A3 | c.3165G>A p.G1055= | Silent (SNP) | VAF 317/670 reads (47%) | called by muse, varscan2
- CPNE4 | c.315G>A p.L105= | Silent (SNP) | VAF 218/390 reads (56%) | catalogued as rs371737129; called by muse, varscan2
- CRISP3 | c.87C>T p.F29= (on ENST00000371159 / NM_001368123.1; = p.F21= on NM_001190986.2) | Silent (SNP) | VAF 215/612 reads (35%) | catalogued as rs868746593; called by muse, mutect2, varscan2
- DNAAF1 | c.1587G>A p.T529= | Silent (SNP) | VAF 217/239 reads (91%) | catalogued as rs769031288; called by muse, varscan2
- DNAAF6 | c.570C>T p.F190= | Silent (SNP) | VAF 173/274 reads (63%) | called by muse, mutect2, varscan2
- DNAH5 | c.8121C>T p.I2707= | Silent (SNP) | VAF 282/480 reads (59%) | catalogued as COSV54213016; called by muse, varscan2
- DOCK9 | c.5781C>T p.F1927= (on ENST00000376460 / NM_001366676.2; = p.F1928= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 164/288 reads (57%) | called by muse, varscan2
- EBLN1 | c.345T>G p.T115= | Silent (SNP) | VAF 14/352 reads (4%) | called by muse, mutect2
- EFHC2 | c.561C>T p.P187= | Silent (SNP) | VAF 258/408 reads (63%) | called by muse, varscan2
- EFL1 | c.1626C>T p.F542= | Silent (SNP) | VAF 112/534 reads (21%) | catalogued as rs368724353; called by muse, mutect2, varscan2
- ELL | c.459C>T p.G153= | Silent (SNP) | VAF 216/464 reads (47%) | called by muse, varscan2
- ELOA3C | c.741G>A p.E247= | Silent (SNP) | VAF 250/2430 reads (10%) | called by muse, varscan2
- EPHA6 | c.501C>T p.Y167= | Silent (SNP) | VAF 212/319 reads (66%) | catalogued as rs1049029555, COSV67568236, COSV67582146; called by muse, varscan2
- EPS8L3 | c.1455G>A p.R485= (on ENST00000361965 / NM_133181.4; = p.R455= on NM_024526.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 255/568 reads (45%) | called by muse, mutect2, varscan2
- EVPL | c.486G>A p.Q162= | Silent (SNP) | VAF 148/321 reads (46%) | catalogued as rs1320767218; called by muse, mutect2, varscan2
- FAM170B | c.165G>A p.R55= | Silent (SNP) | VAF 346/376 reads (92%) | called by muse, mutect2, varscan2
- FAM71D | c.702C>T p.F234= | Silent (SNP) | VAF 253/411 reads (62%) | catalogued as rs891376287, COSV61295401; called by muse, mutect2, varscan2
- FCRL5 | c.1185C>T p.A395= | Silent (SNP) | VAF 240/524 reads (46%) | called by muse, varscan2
- FOXO4 | c.459G>A p.S153= | Silent (SNP) | VAF 116/394 reads (29%) | catalogued as rs761311748, COSV100447144; called by muse, varscan2
- FRMPD3 | c.3276C>T p.F1092= | Silent (SNP) | VAF 216/709 reads (30%) | catalogued as COSV52187365; called by muse, mutect2, varscan2
- GFI1 | c.252G>A p.S84= | Silent (SNP) | VAF 431/938 reads (46%) | called by muse, varscan2
- GON4L | c.1878C>T p.T626= | Silent (SNP) | VAF 172/359 reads (48%) | called by muse, varscan2
- GPR173 | c.894C>A p.L298= | Silent (SNP) | VAF 218/733 reads (30%) | called by muse, mutect2, varscan2
- HIF3A | c.1074A>G p.Q358= (on ENST00000377670 / NM_152795.4; = p.Q289= on NM_022462.4) | Silent (SNP) | VAF 318/643 reads (49%) | called by muse, mutect2, varscan2
- HOXD13 | c.939G>A p.T313= | Silent (SNP) | VAF 468/632 reads (74%) | catalogued as rs150319624; called by muse, mutect2, varscan2
- HTR5A | c.114C>T p.V38= | Silent (SNP) | VAF 369/1206 reads (31%) | catalogued as COSV99839355; called by muse, varscan2
- IFIT3 | c.1371C>T p.F457= | Silent (SNP) | VAF 292/315 reads (93%) | called by muse, mutect2, varscan2
- IGHV3-23 | c.183G>A p.G61= | Silent (SNP) | VAF 216/494 reads (44%) | catalogued as rs782257798; called by muse, varscan2
- ITPR2 | c.2940C>T p.I980= | Silent (SNP) | VAF 135/207 reads (65%) | called by muse, mutect2, varscan2
- KDR | c.1875G>A p.L625= | Silent (SNP) | VAF 288/630 reads (46%) | called by muse, mutect2, varscan2
- KIF26B | c.1434G>A p.K478= | Silent (SNP) | VAF 447/982 reads (46%) | called by muse, mutect2, varscan2
- KIR2DS4 | c.117G>A p.V39= | Silent (SNP) | VAF 224/231 reads (97%) | called by muse, mutect2, varscan2
- KITLG | c.90G>A p.R30= | Silent (SNP) | VAF 232/425 reads (55%) | catalogued as COSV57201358; called by muse, varscan2
- KLHL20 | c.798C>T p.F266= | Silent (SNP) | VAF 207/449 reads (46%) | called by muse, mutect2, varscan2
- KLK12 | c.498C>T p.I166= | Silent (SNP) | VAF 269/604 reads (45%) | catalogued as COSV51578982; called by muse, varscan2
- LAMA1 | c.2343C>T p.S781= | Silent (SNP) | VAF 197/622 reads (32%) | called by muse, varscan2
- LCT | c.2514C>T p.F838= | Silent (SNP) | VAF 475/678 reads (70%) | catalogued as COSV51548641; called by muse, varscan2
- LGALS14 | c.189C>T p.I63= | Silent (SNP) | VAF 222/520 reads (43%) | catalogued as rs1196918495, COSV62372188; called by muse, varscan2
- LRP1B | c.9387G>A p.L3129= | Silent (SNP) | VAF 329/477 reads (69%) | catalogued as rs1432038864; called by muse, mutect2, varscan2
- LRRC14B | c.489C>T p.F163= | Silent (SNP) | VAF 400/682 reads (59%) | catalogued as rs534002505, COSV52045776; called by muse, varscan2
- MGAM2 | c.2700C>T p.F900= | Silent (SNP) | VAF 241/1220 reads (20%) | called by muse, mutect2, varscan2
- MIER2 | c.234C>T p.F78= | Silent (SNP) | VAF 187/426 reads (44%) | called by muse, mutect2, varscan2
- MPEG1 | c.432A>G p.Q144= | Silent (SNP) | VAF 252/423 reads (60%) | called by muse, varscan2
- MTSS1 | c.711C>A p.P237= | Silent (SNP) | VAF 109/711 reads (15%) | called by muse, mutect2, varscan2
- MUC12 | c.7260C>T p.A2420= (on ENST00000379442; = p.A2277= on NM_001164462.1) | Silent (SNP) | VAF 400/3342 reads (12%) | called by muse, varscan2
- MUC16 | c.1782C>T p.S594= | Silent (SNP) | VAF 297/589 reads (50%) | called by muse, mutect2, varscan2
- MUC6 | c.162C>T p.S54= | Silent (SNP) | VAF 430/911 reads (47%) | called by muse, mutect2, varscan2
- MYEOV | c.546G>A p.E182= | Silent (SNP) | VAF 183/598 reads (31%) | catalogued as rs762846844; called by muse, varscan2
- MYO1A | c.2310G>A p.E770= | Silent (SNP) | VAF 80/301 reads (27%) | called by muse, mutect2, varscan2
- MYO7B | c.4599G>A p.K1533= | Silent (SNP) | VAF 572/792 reads (72%) | catalogued as rs903286610; called by muse, mutect2, varscan2
- MYOT | c.276C>T p.S92= | Silent (SNP) | VAF 366/384 reads (95%) | called by muse, varscan2
- NAP1L3 | c.513C>T p.F171= | Silent (SNP) | VAF 170/620 reads (27%) | called by muse, varscan2
- NBPF12 | c.390C>T p.L130= | Silent (SNP) | VAF 254/957 reads (27%) | catalogued as rs1429121487; called by muse, varscan2
- NECTIN3 | c.1134G>A p.E378= | Silent (SNP) | VAF 152/624 reads (24%) | catalogued as COSV60551982; called by muse, mutect2
- NEK11 | c.837C>T p.I279= | Silent (SNP) | VAF 55/208 reads (26%) | catalogued as rs769704761; called by muse, mutect2, varscan2
- NLRP10 | c.1338C>T p.F446= | Silent (SNP) | VAF 404/853 reads (47%) | catalogued as rs1189324356, COSV60781977; called by muse, varscan2
- NLRP12 | c.1086C>T p.I362= | Silent (SNP) | VAF 249/547 reads (46%) | called by muse, mutect2, varscan2
- NPC1L1 | c.2202C>T p.V734= | Silent (SNP) | VAF 281/1011 reads (28%) | called by muse, mutect2, varscan2
- NPNT | c.1531C>T p.L511= | Silent (SNP) | VAF 285/649 reads (44%) | called by muse, mutect2, varscan2
- OR11L1 | c.660C>T p.F220= | Silent (SNP) | VAF 248/512 reads (48%) | catalogued as COSV63313450, COSV63314124; called by muse, varscan2
- OR2I1P | c.48C>T p.F16= | Silent (SNP) | VAF 256/532 reads (48%) | called by muse, varscan2
- OR52L1 | c.42G>A p.L14= | Silent (SNP) | VAF 203/480 reads (42%) | catalogued as COSV59989885; called by muse, varscan2
- P3H1 | c.249C>T p.F83= | Silent (SNP) | VAF 641/1335 reads (48%) | called by muse, mutect2, varscan2
- PEX6 | c.756T>A p.S252= | Silent (SNP) | VAF 401/874 reads (46%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.549G>A p.G183= | Silent (SNP) | VAF 158/338 reads (47%) | catalogued as rs1329747913, COSV65748593; called by muse, mutect2, varscan2
- PLXNA3 | c.579G>A p.A193= | Silent (SNP) | VAF 132/474 reads (28%) | catalogued as rs367789508, COSV100859840, COSV63755056; called by muse, varscan2
- POLR1C | c.450C>T p.P150= | Silent (SNP) | VAF 279/638 reads (44%) | catalogued as rs767689208; called by muse, mutect2, varscan2
- POTEE | c.864G>A p.V288= | Silent (SNP) | VAF 96/871 reads (11%) | catalogued as rs1326371615, COSV58235590; called by muse, mutect2, varscan2
- PRAMEF19 | c.900A>G p.L300= | Silent (SNP) | VAF 351/586 reads (60%) | called by muse, varscan2
- PRICKLE3 | c.1704C>T p.I568= | Silent (SNP) | VAF 194/694 reads (28%) | called by muse, varscan2
- PTGFR | c.153C>T p.L51= | Silent (SNP) | VAF 358/733 reads (49%) | called by muse, mutect2, varscan2
- PTPRB | c.867C>T p.P289= | Silent (SNP) | VAF 153/242 reads (63%) | catalogued as COSV54250456, COSV99717561; called by muse, mutect2, varscan2
- PTX3 | c.1077C>T p.I359= | Silent (SNP) | VAF 275/470 reads (59%) | called by muse, mutect2, varscan2
- RAB44 | c.1299G>A p.R433= | Silent (SNP) | VAF 424/871 reads (49%) | called by muse, mutect2, varscan2
- RERE | c.3129C>T p.G1043= | Silent (SNP) | VAF 286/1034 reads (28%) | catalogued as rs1305864548, COSV61945231; called by muse, varscan2
- RFX7 | c.876A>G p.K292= (on ENST00000559447 / NM_001368074.1; = p.K389= on NM_022841.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 250/528 reads (47%) | called by muse, varscan2
- RNF113A | c.57C>T p.F19= | Silent (SNP) | VAF 190/714 reads (27%) | catalogued as COSV65098010; called by muse, mutect2, varscan2
- SCN10A | c.3075C>T p.I1025= | Silent (SNP) | VAF 72/257 reads (28%) | catalogued as COSV71862710; called by muse, varscan2
- SCN7A | c.3915C>T p.F1305= | Silent (SNP) | VAF 79/312 reads (25%) | called by muse, mutect2, varscan2
- SDSL | c.285C>T p.P95= | Silent (SNP) | VAF 505/938 reads (54%) | catalogued as rs768332846; called by muse, varscan2
- SETD7 | c.984C>T p.I328= | Silent (SNP) | VAF 321/665 reads (48%) | called by muse, mutect2, varscan2
- SHROOM2 | c.4227G>C p.L1409= | Silent (SNP) | VAF 419/2323 reads (18%) | called by muse, mutect2, varscan2
- SLAMF8 | c.291C>T p.D97= | Silent (SNP) | VAF 395/826 reads (48%) | catalogued as rs1298033043; called by muse, mutect2, varscan2
- SLC17A2 | c.1224C>T p.F408= (on ENST00000265425; = p.S359F on NM_005835.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 207/483 reads (43%) | called by muse, mutect2, varscan2
- SOBP | c.147T>C p.D49= | Silent (SNP) | VAF 253/407 reads (62%) | called by muse, mutect2, varscan2
- SPTB | c.4746C>T p.D1582= | Silent (SNP) | VAF 417/676 reads (62%) | catalogued as rs760026396, COSV67630440; called by muse, varscan2
- STARD6 | c.96G>A p.K32= | Silent (SNP) | VAF 89/128 reads (70%) | called by muse, mutect2, varscan2
- STEAP2 | c.12C>T p.I4= | Silent (SNP) | VAF 88/341 reads (26%) | called by muse, mutect2, varscan2
- STK11IP | c.843C>T p.L281= | Silent (SNP) | VAF 279/398 reads (70%) | catalogued as rs1483758915; called by muse, mutect2, varscan2
- SYNE1 | c.25563G>A p.Q8521= (on ENST00000367255 / NM_182961.4; = p.Q8473= on NM_033071.3) | Silent (SNP) | VAF 182/560 reads (33%) | called by muse, varscan2
- TAF4 | c.513C>T p.G171= | Silent (SNP) | VAF 27/78 reads (35%) | called by muse, mutect2, varscan2
- TAS2R1 | c.597C>T p.F199= | Silent (SNP) | VAF 264/400 reads (66%) | called by muse, mutect2, varscan2
- TESK1 | c.1278C>T p.V426= | Silent (SNP) | VAF 1226/1254 reads (98%) | called by muse, mutect2, varscan2
- TINAG | c.1155C>T p.F385= | Silent (SNP) | VAF 136/235 reads (58%) | catalogued as rs1300632056, COSV99450794; called by muse, mutect2, varscan2
- TLN2 | c.2670G>A p.Q890= | Silent (SNP) | VAF 201/1089 reads (18%) | catalogued as rs1448071936; called by muse, mutect2, varscan2
- TLR4 | c.864C>T p.F288= (on ENST00000355622 / NM_138554.5; = p.F248= on NM_003266.4) | Silent (SNP) | VAF 211/219 reads (96%) | catalogued as rs909813445; called by muse, varscan2
- TNIK | c.735C>T p.I245= | Silent (SNP) | VAF 246/380 reads (65%) | catalogued as rs1211378611; called by muse, varscan2
- TPBG | c.1038G>A p.P346= | Silent (SNP) | VAF 151/463 reads (33%) | called by muse, varscan2
- TRAV9-1 | c.153C>T p.S51= | Silent (SNP) | VAF 114/460 reads (25%) | called by muse, varscan2
- TRBV19 | c.39C>T p.L13= | Silent (SNP) | VAF 232/1139 reads (20%) | called by muse, mutect2, varscan2
- TRBV3-1 | c.93C>T p.V31= | Silent (SNP) | VAF 504/1043 reads (48%) | called by muse, varscan2
- TTBK1 | c.27G>A p.K9= | Silent (SNP) | VAF 251/624 reads (40%) | catalogued as rs751441680, COSV52497963; called by muse, mutect2, varscan2
- UNC13C | c.5589C>T p.F1863= | Silent (SNP) | VAF 119/280 reads (43%) | catalogued as rs764281925, COSV52858952; called by muse, mutect2, varscan2
- UNC79 | c.2676C>T p.S892= (on ENST00000393151 / NM_001346218.2; = p.S715= on NM_020818.5) | Silent (SNP) | VAF 102/322 reads (32%) | called by muse, varscan2
- UROC1 | c.804G>A p.V268= | Silent (SNP) | VAF 126/473 reads (27%) | catalogued as COSV52039354; called by muse, mutect2, varscan2
- USH2A | c.11691C>T p.I3897= | Silent (SNP) | VAF 171/405 reads (42%) | called by muse, mutect2, varscan2
- WDR87 | c.4314G>A p.E1438= | Silent (SNP) | VAF 242/542 reads (45%) | catalogued as COSV58206598; called by muse, varscan2
- WDR87 | c.4224G>A p.Q1408= | Silent (SNP) | VAF 212/448 reads (47%) | called by muse, varscan2
- WEE2 | c.408G>A p.L136= | Silent (SNP) | VAF 330/1750 reads (19%) | catalogued as COSV66878917; called by muse, varscan2
- ZNF462 | c.2973C>T p.S991= | Silent (SNP) | VAF 230/242 reads (95%) | called by muse, varscan2
- ZNF724 | c.147G>A p.K49= | Silent (SNP) | VAF 48/272 reads (18%) | catalogued as COSV101369925; called by muse, mutect2, varscan2
- ZSWIM3 | c.702C>T p.L234= | Silent (SNP) | VAF 232/386 reads (60%) | catalogued as rs762881127; called by muse, varscan2
- ACSL5 | c.-136G>A | 5'UTR (SNP) | VAF 287/307 reads (93%) | called by muse, mutect2, varscan2
- ARMCX4 | c.1038+2005C>T | Intron (SNP) | VAF 566/877 reads (65%) | called by muse, mutect2, varscan2
- ATP2B2 | c.*273G>A | 3'UTR (SNP) | VAF 182/648 reads (28%) | called by muse, mutect2, varscan2
- CEP89 | c.39+376T>G | Intron (SNP) | VAF 157/357 reads (44%) | called by muse, mutect2, varscan2
- DNAH7 | c.1353+1606C>T | Intron (SNP) | VAF 89/383 reads (23%) | catalogued as rs1368464110; called by muse, mutect2, varscan2
- DSCR4 | n.411G>A | RNA (SNP) | VAF 148/457 reads (32%) | catalogued as COSV100077261, COSV60301610; called by muse, mutect2, varscan2
- LCE3C | c.-42C>T | 5'UTR (SNP) | VAF 382/818 reads (47%) | called by muse, varscan2
- MARCHF1 | c.242+810G>A | Intron (SNP) | VAF 250/511 reads (49%) | called by muse, mutect2, varscan2
- OPRM1 | c.-490C>T | 5'UTR (SNP) | VAF 95/353 reads (27%) | called by muse, mutect2, varscan2
- PDE2A | c.71+5827C>T | Intron (SNP) | VAF 119/426 reads (28%) | catalogued as rs764845633, COSV57810022; called by muse, varscan2
- SEPTIN3 | chr22:41972532 G>A | 5'Flank (SNP) | VAF 248/746 reads (33%) | called by muse, varscan2
- SIGLEC5 | c.*1G>T | 3'UTR (SNP) | VAF 63/233 reads (27%) | called by muse, mutect2, varscan2
- SLC6A19 | c.*352G>A | 3'UTR (SNP) | VAF 281/448 reads (63%) | catalogued as rs1171294721; called by muse, mutect2, varscan2
- THSD4 | c.-80+14329C>T | Intron (SNP) | VAF 722/1003 reads (72%) | catalogued as rs375345437, COSV100804218; called by muse, varscan2
- TTN | c.10360+1393G>A | Intron (SNP) | VAF 112/443 reads (25%) | catalogued as rs754287881, COSV59985124; called by muse, varscan2
- USH1C | c.1284+5449G>A | Intron (SNP) | VAF 254/573 reads (44%) | called by muse, varscan2
- WBP2 | c.532+28C>T | Intron (SNP) | VAF 348/373 reads (93%) | called by muse, mutect2, varscan2
- WDR45 | c.*246G>A | 3'UTR (SNP) | VAF 110/630 reads (17%) | called by muse, varscan2
